Surgical pathology report (de-identified scan), TCGA case TCGA-90-7766, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-7766-01A (Primary Tumor).

[page 1 of 3]
Final Pathologic Diagnosis:

A. Lung, right middle lobe, nodule, wedge biopsy:

Scar with bronchiolar metaplasia.

Frozen section diagnosis is confirmed.

B. Lymph node, hilar, biopsy:

One benign lymph node (0/1).

C. Lymph nodes, tracheobronchial, regional resection:

Two benign lymph nodes (0/2).

D. Lung, right upper lobe, lobectomy: Squamous cell carcinoma

Specimen: Right upper lobe of lung

Procedure: Lobectomy

Specimen laterality: Unilateral

Tumor site: Right upper lobe

Specimen integrity: Intact

Tumor size: 2.6 cm (greatest dimension)

Tumor focality: Unifocal

Tumor histologic type: Squamous cell carcinoma

Tumor grade: Grade 2

Visceral pleura invasion: Not present

Tumor extension: Confined within right upper lobe of lung

Margins:

Bronchial margin: Uninvolved by invasive carcinoma (frozen section diagnosis confirmed)

Vascular margin: Uninvolved by invasive carcinoma

Parenchymal margin: Uninvolved by invasive carcinoma

Chest wall margin: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 2.2 cm

Specify margin: Parenchymal margin

Treatment effect: Not applicable

Lymph-vascular invasion: Not identified

Pathologic Staging (pTNM):

TNM Descriptors: Not known

Primary tumor (pT): pT1b

Regional lymph nodes (pN): pN0

Number examined: 12 (including parts B, C, E, and F)

Number involved: 0

Distant metastasis (pM): pMx

Additional pathologic findings: None

E. Lymph nodes, paratracheal, regional resection:

Seven benign lymph nodes (0/7).

F. Lymph nodes, subcarinal, regional resection:

Two benign lymph nodes (0/2).

[page 2 of 3]
The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

Frozen section diagnoses are confirmed. Mucicarmine, TTF-1, Napsin A, CK 5/6, and p63 were performed on block D4 in conjunction with appropriately reacting controls to assess for glandular and squamous differentiation. Mucicarmine does not show any intracytoplasmic positivity. The immunohistochemical staining results show the tumor cells are diffusely and strongly positive for CK5/6 and p63, while negative for TTF-1 and Napsin A. These staining results in conjunction with the light microscopic features are consistent with a diagnosis of squamous cell carcinoma.

Intraoperative Consult Diagnosis:

FSA1&2: Right middle lobe:

Negative for malignancy. Features suggestive of pulmonary hamartoma.

F/S TAT: 26 mins.

FSD: Right upper lobe bronchial margin:

Negative for malignancy.

F/S TAT: 13 mins.

Gross Description:

A. Received fresh, labeled "right middle lobe nodule"

is a 5.5 x 4.1 x 1.1 cm lung wedge with attached staple line at one aspect. The pleura is purple-pink, smooth and glistening. The staple line is removed and the underlying tissue inked. Sectioning reveals a 1.3 x 0.9 x 0.8 cm tan-white, rubbery, ill defined, homogeneous nodule that abuts the pleura and comes to within 0.1 cm from the nearest inked stapled margin. The uninvolved parenchyma is tan-pink, soft and homogeneous. A portion of the nodule is submitted for frozen section microscopy as FSA1-FSA2, now in cassettes A1-A2 respectively. Representative uninvolved tissue is submitted in cassette A3.

B. Received in formalin, labeled "hilar lymph node"

is a 1.5 x 1.2 x 0.7 cm tan-red, irregular soft tissue, bisected and entirely submitted in one cassette.

C. Received in formalin, labeled "tracheobronchial

lymph node" are two tan-gray irregular soft tissues, each 1.0 x 0.5 x 0.2 cm, submitted in toto in one cassette.

D. Received fresh, labeled "right upper lobe

bronchial margin" is a 10.7 x 9.0 x 3.9 cm lobe of lung with 0.5 cm of exposed bronchus. The pleura is purple-pink, wrinkled, focally indurated with multiple staple lines extending from the hilum. The staple lines are removed and the underlying tissue inked. Sectioning reveals a 2.6 x 2.1 x 1.5 cm tan, firm, heterogeneous well delineated mass, which abuts the pleura, coming to within 2.2 cm from the nearest stapled margin and 3.5 cm from the bronchial margin. The uninvolved parenchyma is red-pink, soft, heterogeneous with focal distended air spaces. No hilar lymph nodes are identified. The bronchial margin is taken en face and submitted for frozen section microscopy, now in cassette D1.

Representative sections of the remaining tissue are submitted as follows:

D2 vascular margins taken en face;

D3 inked stapled margin, taken perpendicular;

D4 mass to pleura;

[page 3 of 3]
D5-6 random mass;
D7 uninvolved parenchyma.

E. Received in formalin, labeled "paratracheal lymph node" is a 3.5 x 2.5 x 1.3 cm tan, lobulated irregular fatty tissue. Sectioning reveals multiple tan to black anthracotic lymph nodes, up to 2.1 cm.

Representative sections are submitted as follows:

- E1 multiple whole lymph nodes;
- E2 representative section from largest lymph node.

F. Received in formalin, labeled "subcarinal lymph node" is a 3.1 x 1.6 x 1.0 cm tan, lobulated irregular soft tissue. Sectioning reveals two tan-pink, rubbery lymph nodes, 0.5 cm and 2.9 cm.

Representative sections are submitted as follows:

- F1 one whole lymph node;
- F2 representative section from one lymph node.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Source: NCI Genomic Data Commons file 9deab7b8-adde-4118-a5c4-ef0a7f1f886d (TCGA-90-7766.820F1EE0-19CE-4E5E-A3F5-F42A669FF123.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).